Somatic mutation profile of tumor specimen 0DMWTS from CCDI case PBCAKN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdoid tumor, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 16.7 years (6,106 days).
Specimen 0DMWTS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5277c9a9-80bb-4407-8f72-51cb8c5296da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMWTY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8debd7c-3d61-4f84-9509-091b63907179

The open-access MAF lists 13 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 3, 5'UTR 2, Intron 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL22A1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 251/842 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141938188, COSV57333337; called by muse, varscan2
- AIRE | c.1398C>G p.P466= | Splice Region (SNP) | VAF 104/320 reads (33%) | called by muse, varscan2
- COL4A6 | c.4282G>A p.G1428R | Missense Mutation (SNP) | VAF 300/934 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CYP46A1 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 98/436 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, varscan2
- SMARCB1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 350/610 reads (57%) | called by muse, varscan2
- MANEA | c.492G>A p.R164= | Silent (SNP) | VAF 296/885 reads (33%) | called by muse, varscan2
- MCF2L | c.1797C>A p.L599= (on ENST00000375608; = p.L567= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 112/357 reads (31%) | catalogued as COSV100982033; called by muse, varscan2
- MED13 | c.4269A>C p.S1423= | Silent (SNP) | VAF 372/1056 reads (35%) | called by muse, varscan2
- MKI67 | c.4737G>A p.K1579= | Silent (SNP) | VAF 192/1011 reads (19%) | called by muse, varscan2
- NAPSA | c.315G>A p.P105= | Silent (SNP) | VAF 166/573 reads (29%) | catalogued as rs367651287; called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 42/316 reads (13%) | called by muse, varscan2
- SOWAHC | c.-77G>T | 5'UTR (SNP) | VAF 14/50 reads (28%) | called by muse, varscan2
- STK11 | c.1109-13G>A | Intron (SNP) | VAF 92/426 reads (22%) | catalogued as rs568152768; ClinVar: likely benign; called by muse, varscan2
